CCDI case PBCFNK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/9b8ffa5f-0c20-4f13-b110-97b18cdbff26

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.3 years (5,214 days).

Biospecimens (3 samples)
- Samples 0DQSTS, 0DQSTX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQSUR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
